Gene-level copy-number profile of tumor specimen TCGA-A6-6780-01B from TCGA case TCGA-A6-6780, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 74.6 years (27,250 days).
Specimen TCGA-A6-6780-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.2d7c1a55-660a-4075-ad6e-3a3d4da1838d.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A6-6780-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 355 have no estimate.
https://portal.gdc.cancer.gov/files/7ee228c7-dcd3-4e79-8883-d39b99046127

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 519; copy number 2: 59,031; copy number 3: 108; copy number 4: 549; copy number 5: 15; copy number 6: 27; copy number 7: 3; copy number 8: 2; copy number 9: 4; copy number 12: 2; copy number 13: 1; copy number 38: 1; copy number 43: 1.
ABSOLUTE estimates for another vial of this sample (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A6-6780-01A-11D-A274-01): tumor purity 0.69, ploidy 2.05, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:54,086,926–54,087,783, 1 gene: MORF4L2P1.
- chr8:142,910,559–142,917,843, 1 gene: CYP11B2.
- chr11:77,717,712–77,718,411, 1 gene: RSF1-IT2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 56 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:64,941,979–64,942,365, 1 gene, copy number 9: AL606517.1.
- chr1:66,812,885–66,924,856, 1 gene, copy number 5 (within-gene range 1–5): DNAI4.
- chr1:72,301,472–72,301,829, 1 gene, copy number 8: RPL31P12.
- chr1:103,414,879–103,425,465, 1 gene, copy number 13: AC095032.2.
- chr3:130,089,433–130,094,304, 1 gene, copy number 43: LINC02014.
- chr4:9,733,370–9,755,778, 2 genes, copy number 5: AC098976.1, OR7E35P.
- chr4:49,203,171–49,589,529, 19 genes, copy number 6: AC118282.3, AC118282.2, AC118282.4, SNX18P23, AC118282.1, MTCO3P39, MTND3P22, AC119751.3, ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr4:170,343,089–170,372,311, 1 gene, copy number 5: LINC02512.
- chr5:111,070,062–111,078,026, 1 gene, copy number 12 (within-gene range 2–12): TSLP.
- chr7:95,471,835–95,473,998, 1 gene, copy number 5: AC004012.1.
- chr7:111,411,319–111,411,883, 1 gene, copy number 6: AC003989.1.
- chr9:104,598,457–104,599,413, 1 gene, copy number 8: OR13C5.
- chr10:43,136,824–43,138,334, 1 gene, copy number 9: AC010864.1.
- chr12:6,095,699–6,095,970, 1 gene, copy number 38: RN7SL69P.
- chr12:9,948,137–9,995,694, 2 genes, copy number 5 (within-gene range 2–5): CLEC12A-AS1, CLEC12A.
- chr12:111,753,890–111,929,017, 8 genes, copy number 5: AC002996.1, ALDH2, MIR6761, MAPKAPK5-AS1, MAPKAPK5, RPS2P41, ADAM1A, ADAM1B.
- chr12:133,030,389–133,037,222, 2 genes, copy number 7: ZNF84-DT, PTP4A1P2.
- chr14:70,906,657–70,907,111, 1 gene, copy number 9: AC004825.2.
- chr18:49,560,699–49,599,185, 1 gene, copy number 7 (within-gene range 1–7): LIPG.
- chr19:20,175,013–20,177,063, 1 gene, copy number 12: BNIP3P16.
- chr19:22,601,485–22,667,671, 7 genes, copy number 6 (within-gene range 2–6): RN7SL860P, AC011467.3, AC011467.4, RAD54L2P1, LINC01785, AC011467.2, ZNF492.
- chr22:31,388,733–31,388,837, 1 gene, copy number 9: RNU6-338P.

Autosomal genes at a single copy (total copy number 1): 84. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
